Gene-level copy-number profile of tumor specimen TCGA-HD-7831-01A from TCGA case TCGA-HD-7831, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 74.8 years (27,334 days).
Specimen TCGA-HD-7831-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.8c337ca5-fe56-482c-8712-ffa022dcfd9b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HD-7831-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7658f893-82e9-4c89-8c18-f58234cdec30

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 26,946; copy number 2: 28,510; copy number 3: 2,258; copy number 4: 1,231; copy number 5: 735; copy number 6: 1; copy number 7: 45; copy number 10: 78; copy number 13: 2; copy number 30: 1; copy number 32: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HD-7831-01A-11D-2128-01): tumor purity 0.36, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 866 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 5 (broad region; genes not listed).
- chr7:83,355,154–88,756,725, 53 genes, copy number 7–10: AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2, SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1, SOCS5P1, GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1.
- chr7:88,794,106–88,795,737, 1 gene, copy number 10: TEX47.
- chr7:90,466,424–91,210,590, 1 gene, copy number 10 (within-gene range 4–10): CDK14.
- chr7:91,030,149–94,783,525, 67 genes, copy number 5–10 (broad region; genes not listed).
- chr17:50,271,406–50,287,855, 2 genes, copy number 13: TMEM92, TMEM92-AS1.
- chr17:53,952,936–54,771,277, 6 genes, copy number 6–32: AC023934.1, ISCA1P3, AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14.
- chr22:27,978,014–28,679,865, 1 gene, copy number 7 (within-gene range 4–7): TTC28.
- chr22:28,002,484–29,300,525, 25 genes, copy number 7: AL033538.2, RN7SL757P, SNORD42, Y_RNA, MIR5739, RN7SL162P, CHEK2, HSCB, CCDC117, XBP1, Z93930.2, Z93930.3, Z93930.1, ZNRF3, ZNRF3-IT1, ZNRF3-AS1, C22orf31, KREMEN1, AL021393.1, RNU6-810P, RNU6-1219P, EMID1, RHBDD3, AL031186.1, EWSR1.

Autosomal genes at a single copy (total copy number 1): 24,539. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
